TCGA case TCGA-XU-AAXX — Thymoma (TCGA-THYM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Thymic Epithelial Neoplasms; Primary site: Thymus; Tissue source site: University Health Network. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5b7b3e7c-3230-4675-8fdf-3e5119b02ce1

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: Canada; Age at index: 44 years; Vital status: Alive.

Diagnoses (1)
1. Thymoma, type B2, malignant: ICD-O-3 morphology code: 8584/3; ICD-10 code: C37; Tissue or organ of origin: Thymus; Site of resection or biopsy: Thymus; Classification of tumor: primary; Age at diagnosis: 44.5 years (16,265 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; Masaoka stage: Stage IIa; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,721 days (7.4 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 73 days; Days to treatment end: 101 days; Treatment dose: 40 Gy; Number of fractions: 20; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 102 days; Days to treatment end: 108 days; Treatment dose: 10 Gy; Number of fractions: 5; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 2,356 days (6.5 years); Disease response: Tumor Free.
- Days to follow up: 2,363 days (6.5 years); Disease response: Tumor Free.
- Days to follow up: 2,721 days (7.4 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Myasthenia Gravis; Risk factors: Myasthenia Gravis.
- Timepoint category: Initial Diagnosis; Weight: 70 kg; Height: 166 cm; BMI: 25.4.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XU-AAXX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 80 mg.
  Slide TCGA-XU-AAXX-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-XU-AAXX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XU-AAXX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Stage record: Masaoka stage: IIa.
- Primary pathology, Histological type list: Histologic diagnosis: Thymoma, Type B2.
- Primary pathology: Method initial path diagnosis: Median Sternectomy; History myasthenia gravis: Yes.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,721 days; disease-specific survival: no event (censored), 2,721 days; progression-free interval: no event (censored), 2,721 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XU-AAXX-01A-11D-A427-01): tumor purity 0.27, ploidy 2.01, whole-genome doublings 0.
